Somatic mutation profile of tumor specimen TCGA-86-8281-01A (aliquot TCGA-86-8281-01A-11D-2284-08) from TCGA case TCGA-86-8281, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.0 years (27,409 days).
Specimen TCGA-86-8281-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 684304b9-825b-4504-99ae-6a6aca122929.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8281-10A (Blood Derived Normal), aliquot TCGA-86-8281-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b197f17-cb41-47b5-a743-336d6143cf1b

The open-access MAF lists 275 somatic variants for this specimen: 205 protein-altering or splice-affecting, 67 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 174, Silent 67, Nonsense Mutation 16, Splice Site 6, Frame Shift Del 5, Frame Shift Ins 3, RNA 2, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50262468, COSV50595028; called by muse, mutect2, varscan2
- SF3B1 | c.1876A>T p.N626Y | Missense Mutation (SNP) | VAF 27/93 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59206442, COSV59212920, COSV59229378; called by muse, mutect2, varscan2
- ADGRF2 | c.1540C>T p.H514Y (on ENST00000296862 / NM_001368115.2; = p.H446Y on NM_153839.7) | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV99731435; called by muse, mutect2, varscan2
- ADGRL3 | c.2912G>T p.R971L (on ENST00000506720 / NM_001322402.2; = p.R903L on NM_015236.6) | Missense Mutation (SNP) | VAF 116/416 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV72230590, COSV72231107; called by muse, mutect2, varscan2
- ALOXE3 | c.148G>C p.V50L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.385); catalogued as COSV100502995; called by muse, mutect2, varscan2
- AMELY | c.280C>A p.L94M (on ENST00000383036 / NM_001364814.1; = p.L80M on NM_001143.1) | Missense Mutation (SNP) | VAF 76/144 reads (53%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.949); catalogued as COSV99293501; called by muse, mutect2, varscan2
- ARHGAP35 | c.3002C>G p.S1001* | Nonsense Mutation (SNP) | VAF 9/129 reads (7%) | catalogued as COSV101351291; called by muse, mutect2
- ARMH4 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs1446136478, COSV99958529; called by muse, mutect2
- ARPP21 | c.151C>A p.Q51K | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV51800314, COSV51812501; called by muse, mutect2, varscan2
- ATP10A | c.2556G>T p.E852D | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100791379; called by muse, mutect2, varscan2
- ATP13A2 | c.1039G>C p.G347R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100454248; called by muse, mutect2, varscan2
- BCKDHB | c.646A>G p.R216G | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as CM062455, COSV100243776; called by muse, mutect2, varscan2
- BCL9 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as COSV99325438; called by muse, mutect2, varscan2
- BIRC6 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.786); catalogued as COSV101428439; called by muse, mutect2, varscan2
- BRDT | c.1442A>T p.K481M | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV100746495; called by muse, mutect2, varscan2
- C2CD3 | c.4555G>A p.D1519N | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58091163; called by muse, mutect2, varscan2
- CCSER1 | c.1001C>G p.S334C | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.621); catalogued as rs1383349369, COSV100393728; called by muse, mutect2, varscan2
- CD177 | c.361del p.A121Pfs*11 | Frame Shift Del (DEL) | VAF 40/172 reads (23%) | catalogued as rs1555740678, COSV65121540; called by mutect2, pindel, varscan2
- CD33 | c.956C>A p.P319H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV99220587; called by muse, mutect2, varscan2
- CD86 | c.966C>A p.C322* (on ENST00000330540 / NM_175862.5; = p.C316* on NM_006889.4) | Nonsense Mutation (SNP) | VAF 22/102 reads (22%) | catalogued as rs776322796, COSV100053949, COSV100054043; called by muse, mutect2, varscan2
- CDH22 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV100952925; called by muse, mutect2
- CDH8 | c.2320del p.D774Tfs*31 | Frame Shift Del (DEL) | VAF 43/166 reads (26%) | catalogued as COSV54854578, COSV54870384, COSV54881542; called by mutect2, pindel, varscan2
- CEL | c.643G>T p.G215W (on ENST00000673714; = p.G212W on NM_001807.6) | Missense Mutation (SNP) | VAF 119/393 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100672609, COSV60828997; called by muse, mutect2, varscan2
- CHKA | c.1041C>G p.F347L | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV99694303; called by muse, mutect2
- CIP2A | c.1098C>G p.F366L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs776166975, COSV99843009; called by muse, mutect2, varscan2
- COL11A1 | c.3115G>A p.G1039S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764282256, COSV100617257, COSV100617656; called by muse, mutect2, varscan2
- COL6A6 | c.3724C>A p.Q1242K | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.169); catalogued as COSV100650508; called by muse, mutect2, varscan2
- COLGALT2 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 30/260 reads (12%) | catalogued as COSV100730769; called by muse, mutect2, varscan2
- CR2 | c.1559G>C p.R520P | Missense Mutation (SNP) | VAF 193/321 reads (60%) | SIFT tolerated (0.21); PolyPhen benign (0.146); catalogued as COSV100889651, COSV100889672; called by muse, mutect2, varscan2
- CRB1 | c.152A>G p.D51G | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV66348996; called by muse, mutect2, varscan2
- CSF1R | c.543G>T p.M181I | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV53839584; called by muse, mutect2, varscan2
- CSMD1 | c.2760G>T p.W920C (on ENST00000520002; = p.W919C on NM_033225.6) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1231424957, COSV100150351, COSV59312360; called by muse, mutect2
- CSMD1 | c.199C>A p.R67S | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.765); catalogued as rs753420644, COSV101221787, COSV68229471; called by muse, mutect2, varscan2
- CYLC2 | c.427A>G p.K143E | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as COSV100872485; called by muse, mutect2, varscan2
- DLGAP2 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101422276; called by muse, mutect2
- DMXL2 | c.272A>T p.H91L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.5); catalogued as COSV99196625; called by muse, mutect2
- DPRX | c.49C>A p.H17N | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as COSV100934097; called by muse, mutect2, varscan2
- ECHS1 | c.515-1G>T p.X172_splice | Splice Site (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100881918; called by muse, mutect2
- EMSY | c.3203A>G p.Y1068C | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV100595818; called by muse, mutect2, varscan2
- EXOC5 | c.1707G>C p.L569F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.276); catalogued as COSV100567166; called by muse, mutect2
- EXTL2 | c.240G>C p.L80F | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.973); catalogued as COSV100921114; called by muse, mutect2
- FAT4 | c.3004G>T p.E1002* | Nonsense Mutation (SNP) | VAF 80/254 reads (31%) | catalogued as COSV101272515; called by muse, mutect2, varscan2
- FBXL7 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs576303242, COSV61641769; called by muse, mutect2, varscan2
- FIG4 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.596); catalogued as COSV100019934, COSV57789410; called by muse, mutect2
- FLG2 | c.2783G>A p.G928D | Missense Mutation (SNP) | VAF 173/1144 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV101166008, COSV66172452; called by muse, mutect2, varscan2
- FLNA | c.4598+1G>T p.X1533_splice | Splice Site (SNP) | VAF 56/156 reads (36%) | catalogued as COSV100774878; called by muse, mutect2, varscan2
- FLNB | c.6380G>T p.S2127I | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.197); catalogued as COSV99913828; called by muse, mutect2, varscan2
- FLT4 | c.2675C>A p.A892E | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56121298, COSV99987729; called by muse, mutect2, varscan2
- FOXK2 | c.1982A>T p.*661Lext*51 | Nonstop Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as COSV100082239; called by muse, mutect2, varscan2
- GAK | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100033804; called by muse, mutect2, varscan2
- GARRE1 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100209565; called by muse, mutect2, varscan2
- GAS2L1 | c.791T>C p.L264P | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99329588; called by muse, mutect2, varscan2
- GBGT1 | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100923780; called by muse, mutect2, varscan2
- GFOD1 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 67/318 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101014550; called by muse, mutect2, varscan2
- GLIS1 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as rs1200151266, COSV100389759, COSV100390340; called by muse, mutect2, varscan2
- GLYATL2 | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.528); catalogued as rs376089911; called by muse, varscan2
- GNA13 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV101457484; called by muse, mutect2, varscan2
- GPC3 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 276/392 reads (70%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV100893156; called by muse, mutect2, varscan2
- HAT1 | c.546G>C p.L182F | Missense Mutation (SNP) | VAF 66/299 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV99908024; called by muse, mutect2, varscan2
- HEATR1 | c.3112G>C p.A1038P | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV100857702, COSV63983609; called by muse, mutect2, varscan2
- HES3 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64938639; called by muse, mutect2, varscan2
- HOXA4 | c.621C>G p.N207K | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100415557; called by muse, mutect2, varscan2
- HUWE1 | c.5514G>T p.M1838I | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV99473076; called by muse, mutect2, varscan2
- IFNA8 | c.392A>T p.E131V | Missense Mutation (SNP) | VAF 68/313 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV101206916; called by muse, mutect2, varscan2
- IGLV2-14 | c.155A>G p.N52S | Missense Mutation (SNP) | VAF 187/756 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as rs767924873; called by muse, mutect2
- IGSF9B | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100317978; called by muse, mutect2
- IQCH | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.231); catalogued as COSV100246060; called by muse, mutect2, varscan2
- ISL1 | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV100045557; called by muse, mutect2, varscan2
- ITGA8 | c.90G>C p.L30F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV100959424; called by muse, mutect2
- ITIH1 | c.1285C>A p.P429T | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.838); catalogued as COSV99835404; called by muse, mutect2, varscan2
- ITPRID1 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 17/269 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV100086831; called by muse, mutect2
- JPH2 | c.53G>T p.W18L | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100652600; called by muse, mutect2, varscan2
- KCNN3 | c.1117T>A p.C373S | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.279); catalogued as COSV99678711; called by muse, mutect2, varscan2
- KIF3B | c.2027A>G p.E676G | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV100996411; called by muse, mutect2
- KLHL31 | c.1361T>C p.V454A | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100911809; called by muse, mutect2, varscan2
- KMT2B | c.8035C>T p.R2679C | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV53073840; called by muse, mutect2, varscan2
- LAMA4 | c.1027G>A p.E343K (on ENST00000230538 / NM_001105206.3; = p.E336K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/306 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.071); catalogued as COSV100038805; called by muse, mutect2
- LATS1 | c.3088A>G p.I1030V | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.262); catalogued as COSV53594712; called by muse, mutect2
- LCE1D | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 64/452 reads (14%) | PolyPhen benign (0.201); catalogued as COSV100405917; called by muse, mutect2
- LHX9 | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100435971; called by muse, mutect2, varscan2
- LIG4 | c.1837A>G p.K613E | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV100799968; called by muse, mutect2, varscan2
- LMAN2L | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as COSV99383476, COSV99383641; called by muse, mutect2, varscan2
- LMNTD2 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as rs200625515; called by muse, mutect2, varscan2
- LRRC8B | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 73/298 reads (24%) | catalogued as COSV100446620; called by muse, mutect2, varscan2
- MACF1 | c.1264G>T p.A422S | Missense Mutation (SNP) | VAF 36/131 reads (27%) | catalogued as COSV100485327; called by muse, mutect2, varscan2
- MAGEC2 | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 93/290 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99909730; called by muse, mutect2, varscan2
- MROH9 | c.438C>G p.I146M | Missense Mutation (SNP) | VAF 63/318 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100882843; called by muse, mutect2, varscan2
- MUC13 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV100222394; called by muse, mutect2, varscan2
- MUC16 | c.31028C>A p.S10343* | Nonsense Mutation (SNP) | VAF 29/120 reads (24%) | catalogued as COSV101200369; called by muse, mutect2, varscan2
- MYEOV | c.10A>G p.R4G | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs760346760, COSV100456681; called by muse, varscan2
- NDST1 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99938916; called by muse, mutect2, varscan2
- NDST4 | c.905G>T p.R302M | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99997014; called by muse, mutect2, varscan2
- NELL1 | c.2027C>G p.P676R | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV100121614, COSV100122560; called by muse, mutect2, varscan2
- NEUROD1 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.027); catalogued as COSV99716972; called by muse, mutect2, varscan2
- NFASC | c.755C>A p.T252N (on ENST00000339876 / NM_001378329.1; = p.T263N on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/434 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV100364599, COSV58362972; called by muse, mutect2
- NLRC5 | c.5302C>A p.P1768T | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV99347701; called by muse, mutect2, varscan2
- NOP58 | c.426G>T p.L142F | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99970701; called by muse, mutect2, varscan2
- NOVA2 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV99611456; called by muse, mutect2, varscan2
- NPAP1 | c.1541A>T p.E514V | Missense Mutation (SNP) | VAF 161/630 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV100275645; called by muse, mutect2, varscan2
- NSMAF | c.1310A>T p.D437V | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.422); catalogued as COSV99233146; called by muse, mutect2, varscan2
- NT5C1B | c.1060C>A p.R354S (on ENST00000359846 / NM_001199086.2; = p.R294S on NM_033253.4) | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.154); catalogued as COSV100410143; called by muse, mutect2, varscan2
- NUDT19 | c.1066G>T p.V356F | Missense Mutation (SNP) | VAF 85/301 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV101229237; called by muse, mutect2, varscan2
- NXF3 | c.1396G>T p.G466C | Missense Mutation (SNP) | VAF 206/312 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV67702718; called by muse, mutect2, varscan2
- OR14J1 | c.73C>A p.H25N | Missense Mutation (SNP) | VAF 112/260 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV101012813; called by muse, mutect2, varscan2
- OR2B3 | c.888T>A p.D296E | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV101013816; called by muse, mutect2, varscan2
- OR2T2 | c.578C>A p.T193K | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100737721, COSV61617901; called by muse, mutect2, varscan2
- OR2W3 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 69/301 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); catalogued as rs1365371916, COSV64457182, COSV64457996; called by muse, mutect2, varscan2
- OR5B12 | c.320C>G p.T107S | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.056); catalogued as COSV100222477; called by muse, mutect2, varscan2
- OR5B17 | c.817T>C p.S273P | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as rs200495594, COSV100641924; called by muse, mutect2, varscan2
- OR9G1 | c.493T>A p.F165I | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100380472; called by muse, mutect2, varscan2
- ORC1 | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.157); catalogued as COSV100856705; called by muse, mutect2, varscan2
- OTOR | c.148T>A p.Y50N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99856250; called by muse, mutect2, varscan2
- OTULINL | c.650G>C p.R217T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV99947236; called by muse, mutect2, varscan2
- PAG1 | c.563A>G p.K188R | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367869276; called by muse, mutect2, varscan2
- PARD3 | c.3540G>T p.E1180D | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.156); catalogued as COSV100632591; called by muse, mutect2, varscan2
- PCDH15 | c.1130C>G p.A377G | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as COSV100223438; called by muse, mutect2, varscan2
- PCDHB7 | c.1993G>T p.G665C | Missense Mutation (SNP) | VAF 71/553 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50799178, COSV99177125; called by muse, mutect2, varscan2
- PCDHGB1 | c.1552C>A p.H518N | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs572024020, COSV99541699; called by muse, mutect2, varscan2
- PDGFRA | c.1751C>A p.S584* | Nonsense Mutation (SNP) | VAF 42/165 reads (25%) | catalogued as COSV99957070, COSV99957222; called by muse, mutect2, varscan2
- PHC1 | c.1891C>G p.P631A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs1467768771, COSV101418652; called by muse, mutect2
- PHKB | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100067828; called by muse, mutect2
- PIK3CG | c.1296G>T p.Q432H | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as COSV100782995; called by muse, mutect2, varscan2
- PKD2 | c.2678G>A p.R893K | Missense Mutation (SNP) | VAF 136/637 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV99417535; called by muse, mutect2, varscan2
- PKD2 | c.2679G>C p.R893S | Missense Mutation (SNP) | VAF 137/627 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV99417541; called by muse, mutect2, varscan2
- PLG | c.490T>A p.C164S | Missense Mutation (SNP) | VAF 114/349 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99804862; called by muse, mutect2, varscan2
- POC1B | c.100+1G>A p.X34_splice | Splice Site (SNP) | VAF 24/114 reads (21%) | catalogued as COSV100544347; called by muse, mutect2, varscan2
- PPP1R9A | c.1743G>C p.K581N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV99196344; called by muse, mutect2
- PRDX6 | c.644A>G p.K215R | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV100458515; called by muse, mutect2, varscan2
- PSG5 | c.753C>G p.Y251* | Nonsense Mutation (SNP) | VAF 117/434 reads (27%) | catalogued as COSV100742912, COSV61655276; called by muse, mutect2, varscan2
- PSIP1 | c.353C>G p.S118* | Nonsense Mutation (SNP) | VAF 15/254 reads (6%) | catalogued as COSV101050967; called by muse, mutect2
- PTPRZ1 | c.2219C>A p.T740K | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.337); catalogued as COSV66437919; called by muse, mutect2, varscan2
- PXDNL | c.3437G>T p.R1146I | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100684750; called by muse, mutect2, varscan2
- RB1CC1 | c.3892G>T p.E1298* | Nonsense Mutation (SNP) | VAF 34/125 reads (27%) | catalogued as COSV99212437; called by muse, mutect2, varscan2
- RBP3 | c.724A>G p.I242V | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.351); catalogued as rs1462322400; called by muse, mutect2, varscan2
- RFNG | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs772335800, COSV100136058; called by muse, mutect2
- RFX3 | c.1441A>G p.M481V | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100175427; called by muse, mutect2, varscan2
- RGS16 | c.394A>G p.I132V | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs201461121, COSV100842494; called by muse, mutect2, varscan2
- RHOJ | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100370388; called by muse, mutect2
- ROBO4 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as rs755801141, COSV60621702; called by muse, mutect2
- RYR1 | c.2924G>T p.R975L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as COSV100616211; called by muse, mutect2
- SCN3A | c.5636T>A p.M1879K | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99327520; called by muse, mutect2, varscan2
- SDHA | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99371884; called by muse, mutect2, varscan2
- SELP | c.2084T>A p.V695E | Missense Mutation (SNP) | VAF 1120/1907 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV99740383; called by muse, mutect2, varscan2
- SERPINA11 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100594078, COSV58240982; called by muse, mutect2, varscan2
- SETBP1 | c.4057G>T p.G1353C | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.398); catalogued as COSV99953892; called by muse, mutect2, varscan2
- SH2D5 | c.889G>T p.A297S (on ENST00000444387 / NM_001103161.2; = p.A213S on NM_001103160.2) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.915); catalogued as COSV100903871; called by muse, mutect2, varscan2
- SIK3 | c.704G>T p.G235V (on ENST00000445177 / NM_001366686.2; = p.G241V on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99408321; called by muse, mutect2, varscan2
- SLC17A8 | c.123G>C p.E41D | Missense Mutation (SNP) | VAF 83/380 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100035682; called by muse, mutect2, varscan2
- SLC9A3 | c.408C>G p.F136L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99376375; called by muse, mutect2, varscan2
- SLC9B1 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV99599803; called by muse, varscan2
- SMARCA4 | c.2654G>T p.R885L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM134626, COSV60786075, COSV60808047; called by muse, mutect2
- SMARCD1 | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV101202961; called by muse, mutect2, varscan2
- SPEF2 | c.979-1G>A p.X327_splice | Splice Site (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99214473; called by muse, mutect2, varscan2
- SRCAP | c.6393C>A p.D2131E | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99350580; called by muse, mutect2, varscan2
- ST8SIA3 | c.951C>A p.H317Q | Missense Mutation (SNP) | VAF 38/116 reads (33%) | PolyPhen probably damaging (0.966); catalogued as COSV100129600; called by muse, mutect2, varscan2
- STON2 | c.1794C>A p.F598L (on ENST00000649389 / NM_001366849.2; = p.F541L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as COSV50856296, COSV99964916; called by muse, mutect2, varscan2
- SYNJ1 | c.2449G>T p.V817L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.046); catalogued as COSV100449451; called by muse, mutect2, varscan2
- TDRD7 | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100795710; called by muse, mutect2, varscan2
- TECRL | c.909C>A p.Y303* | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as COSV101169138, COSV101169217; called by muse, mutect2, varscan2
- TEP1 | c.1731G>T p.E577D | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV99402746; called by muse, mutect2, varscan2
- TEX14 | c.4447G>A p.E1483K (on ENST00000240361 / NM_001201457.2; = p.E1437K on NM_031272.5) | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs768042608, COSV99541040; called by muse, mutect2, varscan2
- THPO | c.648+1G>A p.X216_splice (on ENST00000649095 / NM_001290003.1; = p.X76_splice on NM_000460.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 55/193 reads (28%) | catalogued as COSV99200524; called by muse, mutect2, varscan2
- THSD7B | c.1743T>A p.S581R | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.255); catalogued as COSV99753911; called by muse, mutect2, varscan2
- TIAM2 | c.4844A>G p.K1615R (on ENST00000529824; = p.K1586R on NM_012454.3) | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.09); catalogued as COSV99265701; called by muse, mutect2, varscan2
- TINF2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV99945602; called by muse, mutect2, varscan2
- TMTC1 | c.2140C>A p.P714T (on ENST00000539277 / NM_001193451.2; = p.P606T on NM_175861.3) | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99760174; called by muse, mutect2, varscan2
- TOB1 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV99278876; called by muse, varscan2
- TTC12 | c.2102A>T p.Y701F | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs1457233588, COSV100133198; called by muse, mutect2, varscan2
- UBTF | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 18/298 reads (6%) | catalogued as COSV100256008; called by muse, mutect2
- USP15 | c.842G>C p.R281T (on ENST00000280377 / NM_001351159.2; = p.R252T on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.165); catalogued as COSV99739993; called by muse, mutect2, varscan2
- VPS39 | c.1753C>T p.R585C (on ENST00000348544 / NM_001301138.2; = p.R574C on NM_015289.5) | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs191703716, COSV58791433; called by muse, mutect2, varscan2
- VWA3A | c.1840C>A p.L614I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV100241065; called by muse, mutect2, varscan2
- WDR49 | c.1093G>A p.D365N (on ENST00000308378 / NM_001366158.1; = p.D706N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV100393193; called by muse, mutect2, varscan2
- WDR64 | c.1156T>A p.S386T | Missense Mutation (SNP) | VAF 92/145 reads (63%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV100843859; called by muse, mutect2, varscan2
- WDR72 | c.1606G>T p.D536Y | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100854741; called by muse, mutect2, varscan2
- XIRP1 | c.4431G>T p.Q1477H | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV100453762; called by muse, mutect2, varscan2
- ZAN | c.4805T>C p.V1602A | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100769912; called by muse, mutect2, varscan2
- ZBTB32 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); catalogued as rs369211573; called by muse, mutect2, varscan2
- ZC3H13 | c.1313A>T p.Q438L | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.037); catalogued as COSV99668506; called by muse, mutect2, varscan2
- ZFYVE9 | c.1858A>T p.K620* | Nonsense Mutation (SNP) | VAF 54/189 reads (29%) | catalogued as COSV99819752; called by muse, mutect2, varscan2
- ZFYVE9 | c.1859A>T p.K620I | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99820306; called by muse, mutect2, varscan2
- ZNF208 | c.2220G>T p.K740N | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101237097; called by muse, varscan2
- ZNF221 | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 47/154 reads (31%) | catalogued as rs148293806; called by muse, mutect2, varscan2
- ZNF235 | c.532A>T p.K178* | Nonsense Mutation (SNP) | VAF 45/134 reads (34%) | catalogued as COSV99349558; called by muse, mutect2, varscan2
- ZNF347 | c.2495C>T p.P832L | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.021); catalogued as COSV61968782; called by muse, mutect2, varscan2
- ZNF423 | c.1108G>T p.G370C (on ENST00000563137 / NM_001379286.1; = p.G362C on NM_015069.4) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.651); catalogued as COSV99282559; called by muse, mutect2, varscan2
- ZNF431 | c.1216G>T p.G406C | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100218876; called by muse, mutect2, varscan2
- ZNF532 | c.1124G>T p.R375I | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100266816; called by muse, mutect2, varscan2
- ZNF536 | c.1949C>G p.S650C | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777988063, COSV100835440; called by muse, mutect2, varscan2
- ZNF536 | c.3123C>A p.C1041* | Nonsense Mutation (SNP) | VAF 34/163 reads (21%) | catalogued as COSV100835442; called by muse, mutect2
- ZNF606 | c.305-2A>C p.X102_splice | Splice Site (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100357443; called by muse, mutect2, varscan2
- ZNF99 | c.117C>A p.N39K | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs934117013, COSV101233875; called by muse, mutect2, varscan2
- AMER1 | c.3074A>T p.H1025L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, varscan2
- ATAD2 | c.1802_1803dup p.E602Kfs*8 | Frame Shift Ins (INS) | VAF 38/147 reads (26%) | called by mutect2, pindel, varscan2
- IGHV2-26 | c.265A>C p.T89P | Missense Mutation (SNP) | VAF 78/279 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, varscan2
- IGHV3OR16-8 | c.100G>T p.G34W | Missense Mutation (SNP) | VAF 94/438 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV4-69 | c.100C>A p.L34M | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- KIF1A | c.1705_1706insT p.G569Vfs*20 | Frame Shift Ins (INS) | VAF 13/90 reads (14%) | called by mutect2, pindel*
- MUC2 | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- PPEF2 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- RASAL2 | c.921dup p.V308Cfs*13 | Frame Shift Ins (INS) | VAF 144/302 reads (48%) | called by mutect2, pindel, varscan2
- RBP3 | c.1814C>A p.A605D | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- RGS18 | c.383del p.P128Lfs*66 | Frame Shift Del (DEL) | VAF 30/166 reads (18%) | called by mutect2, pindel, varscan2
- TRAF4 | c.740_743del p.L247Rfs*27 | Frame Shift Del (DEL) | VAF 23/88 reads (26%) | called by mutect2, varscan2
- WHRN | c.2117del p.P706Hfs*33 | Frame Shift Del (DEL) | VAF 41/200 reads (21%) | called by mutect2, pindel, varscan2
- AACS | c.1473C>T p.I491= | Silent (SNP) | VAF 133/645 reads (21%) | catalogued as COSV99908144; called by muse, mutect2, varscan2
- ALDH8A1 | c.630C>A p.T210= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs544667948, COSV55641571; called by muse, mutect2, varscan2
- ALOX5 | c.741G>A p.R247= | Silent (SNP) | VAF 63/226 reads (28%) | catalogued as COSV65554393; called by muse, mutect2, varscan2
- APOB | c.4005C>T p.F1335= | Silent (SNP) | VAF 45/185 reads (24%) | catalogued as COSV99266481; called by muse, mutect2, varscan2
- AVPR1B | c.597C>T p.Y199= | Silent (SNP) | VAF 56/403 reads (14%) | catalogued as COSV100899400; called by muse, mutect2, varscan2
- CDH12 | c.243C>T p.D81= | Silent (SNP) | VAF 44/201 reads (22%) | catalogued as COSV101202855; called by muse, mutect2, varscan2
- CHST3 | c.504C>T p.I168= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs370284531; called by muse, mutect2, varscan2
- COL26A1 | c.726C>A p.P242= (on ENST00000313669 / NM_001278563.3; = p.P240= on NM_133457.4) | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100561886; called by muse, mutect2, varscan2
- CRIP2 | c.459C>T p.C153= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as rs782485931, COSV61274956; called by muse, mutect2, varscan2
- CRLF2 | c.9G>A p.R3= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs747962265, COSV101053751; called by muse, mutect2, varscan2
- CSF2RB | c.963C>A p.V321= | Silent (SNP) | VAF 39/183 reads (21%) | catalogued as COSV99454102; called by muse, mutect2, varscan2
- CYGB | c.99G>T p.R33= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV99506188; called by muse, mutect2, varscan2
- DRAM1 | c.495C>T p.A165= | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as rs372136588; called by muse, mutect2, varscan2
- ELOVL4 | c.237C>A p.L79= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV100876338; called by muse, mutect2, varscan2
- ENG | c.1632C>A p.T544= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as COSV100785315; called by muse, mutect2, varscan2
- FHL5 | c.339C>G p.S113= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV100459557; called by muse, mutect2, varscan2
- FRMD1 | c.189G>T p.R63= | Silent (SNP) | VAF 77/212 reads (36%) | catalogued as COSV99349926; called by muse, mutect2, varscan2
- GLYATL2 | c.660C>A p.S220= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV99780430; called by muse, varscan2
- GNRHR | c.495C>A p.I165= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99892252; called by muse, mutect2, varscan2
- GPA33 | c.381C>A p.G127= | Silent (SNP) | VAF 29/188 reads (15%) | catalogued as COSV100901137; called by muse, mutect2, varscan2
- GPATCH1 | c.1221A>T p.T407= | Silent (SNP) | VAF 35/138 reads (25%) | catalogued as COSV99404152; called by muse, mutect2, varscan2
- GRIN2D | c.2118G>A p.P706= | Silent (SNP) | VAF 59/241 reads (24%) | catalogued as rs768616486, COSV54378695; called by muse, mutect2, varscan2
- HGFAC | c.1224C>T p.I408= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs370096728; called by muse, mutect2, varscan2
- HMCN1 | c.13561A>C p.R4521= | Silent (SNP) | VAF 291/502 reads (58%) | catalogued as COSV99631673; called by muse, mutect2, varscan2
- IL4R | c.747G>T p.L249= | Silent (SNP) | VAF 58/223 reads (26%) | catalogued as COSV99405158; called by muse, mutect2, varscan2
- INTS5 | c.1404C>T p.P468= | Silent (SNP) | VAF 69/265 reads (26%) | catalogued as COSV100399703; called by muse, mutect2, varscan2
- KALRN | c.6657G>A p.Q2219= (on ENST00000360013 / NM_001024660.4; = p.Q522= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as rs1238481278, COSV99362417; called by muse, mutect2
- KCNJ16 | c.267C>A p.G89= | Silent (SNP) | VAF 36/162 reads (22%) | catalogued as COSV99388470; called by muse, mutect2, varscan2
- KDM3B | c.2667G>A p.K889= | Silent (SNP) | VAF 32/160 reads (20%) | catalogued as COSV100069895; called by muse, mutect2, varscan2
- KIF26A | c.3225C>T p.I1075= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100181331; called by muse, mutect2
- KLHL34 | c.1155C>A p.A385= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV101069955; called by mutect2, varscan2
- LARGE1 | c.1162C>A p.R388= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV100505842, COSV61674817; called by muse, mutect2, varscan2
- LELP1 | c.219C>G p.P73= | Silent (SNP) | VAF 43/251 reads (17%) | catalogued as rs769637188, COSV100907349; called by muse, mutect2, varscan2
- LENG8 | c.1377C>T p.P459= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as COSV100457792; called by muse, mutect2, varscan2
- LRFN1 | c.1578G>T p.P526= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs1482893047, COSV50439085, COSV99953092; called by muse, mutect2, varscan2
- LRTM1 | c.39C>A p.V13= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99836116; called by muse, mutect2, varscan2
- MGAT3 | c.750G>T p.P250= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as COSV100361979; called by muse, mutect2, varscan2
- MMP9 | c.1215C>T p.H405= | Silent (SNP) | VAF 43/225 reads (19%) | catalogued as rs200610760, COSV100812428; called by muse, mutect2, varscan2
- MUTYH | c.480C>A p.A160= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as COSV100588073; called by muse, mutect2, varscan2
- NALCN | c.507T>C p.N169= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as rs778186193, COSV99216207; called by muse, mutect2, varscan2
- NFASC | c.756C>T p.T252= (on ENST00000339876 / NM_001378329.1; = p.T263= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/439 reads (10%) | catalogued as rs758982898, COSV100364056; called by muse, mutect2
- NRXN1 | c.1116C>A p.V372= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV100455822; called by muse, mutect2, varscan2
- OR10T2 | c.247C>T p.L83= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV100555011; called by muse, mutect2, varscan2
- OR2T12 | c.90G>T p.L30= | Silent (SNP) | VAF 274/450 reads (61%) | catalogued as COSV100527868; called by muse, varscan2
- OR2W3 | c.315G>T p.L105= | Silent (SNP) | VAF 67/302 reads (22%) | catalogued as COSV100831740; called by muse, mutect2, varscan2
- OR52M1 | c.429G>T p.V143= | Silent (SNP) | VAF 45/159 reads (28%) | catalogued as COSV100798599, COSV64173021; called by muse, mutect2, varscan2
- OR6K6 | c.138G>T p.P46= (on ENST00000368144; = p.P22= on NM_001005184.1) | Silent (SNP) | VAF 197/404 reads (49%) | catalogued as rs199918253, COSV100933755; called by muse, mutect2, varscan2
- OR7A17 | c.132C>A p.L44= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV100541631; called by muse, mutect2, varscan2
- PASK | c.2127G>T p.T709= | Silent (SNP) | VAF 60/209 reads (29%) | catalogued as COSV99299521; called by muse, mutect2, varscan2
- PCDHGA2 | c.2046C>A p.A682= | Silent (SNP) | VAF 184/563 reads (33%) | catalogued as COSV53929113; called by muse, mutect2, varscan2
- PKDREJ | c.5031C>T p.I1677= | Silent (SNP) | VAF 60/164 reads (37%) | catalogued as rs373271693; called by muse, mutect2, varscan2
- PLEKHH1 | c.975C>T p.I325= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs754288357, COSV100233294; called by muse, mutect2
- PLPPR5 | c.159C>A p.P53= | Silent (SNP) | VAF 10/177 reads (6%) | catalogued as COSV54172795, COSV99587423; called by muse, mutect2
- POM121L12 | c.498C>A p.A166= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV101374941; called by muse, mutect2, varscan2
- PPEF2 | c.495G>T p.R165= | Silent (SNP) | VAF 46/235 reads (20%) | catalogued as COSV54423058, COSV99714987; called by muse, mutect2, varscan2
- PRDX1 | c.177C>T p.F59= | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as rs760500844, COSV99423652; called by muse, mutect2, varscan2
- RABGEF1 | c.798G>T p.L266= (on ENST00000439720 / NM_001287061.2; = p.L253= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV99534929; called by muse, mutect2, varscan2
- SALL3 | c.2913G>T p.R971= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV101610022, COSV73306472; called by muse, mutect2, varscan2
- SEMA6D | c.1794C>A p.T598= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100317232; called by muse, mutect2, varscan2
- SLC2A10 | c.933C>T p.V311= | Silent (SNP) | VAF 43/192 reads (22%) | catalogued as COSV100826383; called by muse, mutect2, varscan2
- SLC7A13 | c.732T>A p.T244= | Silent (SNP) | VAF 98/287 reads (34%) | catalogued as COSV99879017; called by muse, mutect2, varscan2
- SP140 | c.375T>C p.D125= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as COSV100613909; called by muse, mutect2, varscan2
- ST3GAL2 | c.96C>T p.A32= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV100735713; called by muse, mutect2
- TXK | c.1062T>C p.Y354= | Silent (SNP) | VAF 62/272 reads (23%) | catalogued as COSV99972587; called by muse, mutect2, varscan2
- UNC13B | c.4260G>T p.V1420= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as COSV100266767; called by muse, mutect2, varscan2
- ZBTB20 | c.294C>T p.R98= (on ENST00000474710 / NM_001164342.2; = p.R25= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV100614268; called by muse, mutect2, varscan2
- ZFY | c.279C>A p.V93= | Silent (SNP) | VAF 96/164 reads (59%) | catalogued as COSV99324243; called by muse, mutect2, varscan2
- GLRXP3 | n.292C>T | RNA (SNP) | VAF 60/178 reads (34%) | catalogued as rs772018873; called by muse, mutect2, varscan2
- GRM8 | c.727+48373G>T | Intron (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100284216, COSV58810927; called by muse, mutect2
- SSPOP | n.1238C>T | RNA (SNP) | VAF 8/39 reads (21%) | catalogued as COSV50487582; called by muse, mutect2
